Gene-level copy-number profile of tumor specimen MP2PRT-PAVAVX-TBP1-A from MP2PRT case MP2PRT-PAVAVX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,428 days).
Specimen MP2PRT-PAVAVX-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 39759d58-2dec-4a02-b9a5-8166de75f9c5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVAVX-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/2dbc1d18-8a11-4d99-b67e-189352c0a2ea

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 296; copy number 1: 3,829; copy number 2: 54,640; copy number 3: 133.

Homozygous deletions (total copy number 0; autosomes only): 296 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,295,455, 47 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36.
- chr2:89,989,987–89,990,221, 1 gene: IGKV3D-25.
- chr3:112,332,347–112,499,472, 3 genes (within-gene range 0–2): CD200, AC092894.1, BTLA.
- chr3:177,010,719–178,007,779, 18 genes: MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P.
- chr3:187,120,948–187,180,908, 1 gene: RPL39L.
- chr7:38,239,580–38,378,804, 24 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.
- chr10:109,996,368–110,135,565, 1 gene (within-gene range 0–2): ADD3.
- chr14:22,449,113–22,459,156, 5 genes (within-gene range 0–2): TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3.
- chr14:22,483,004–22,497,718, 13 genes (within-gene range 0–2): TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41.
- chr14:93,437,400–93,437,510, 1 gene (within-gene range 0–2): RNU6-1258P.
- chr14:105,672,308–106,637,973, 153 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,657,725–106,715,181, 12 genes (within-gene range 0–2): IGHV3-64, IGHV3-65, IGHVII-65-1, IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69.
- chr22:22,030,934–22,088,085, 13 genes (within-gene range 0–2): IGLV4-69, IGLVI-68, AC245452.4, AC245452.3, IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5.
- chr22:22,219,647–22,245,515, 4 genes: IGLVIV-53, TOP3BP1, AC245060.3, VPREB1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 973. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
